Somatic mutation profile of tumor specimen MP2PRT-PAPPEJ-TMP1-A (aliquot MP2PRT-PAPPEJ-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPPEJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.6 years (2,406 days).
Specimen MP2PRT-PAPPEJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2fb18c40-5d46-4aaf-b6c7-0657b7263e60.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPPEJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPPEJ-NB1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e945924d-43bf-4c0b-a6f1-998c850861c7

The open-access MAF lists 32 somatic variants for this specimen: 24 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 6, Nonsense Mutation 2, 5'UTR 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC51 | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 78/335 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as rs1434772617; called by muse, mutect2, varscan2
- CUL7 | c.4319G>A p.R1440Q | Missense Mutation (SNP) | VAF 36/397 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs779355111, COSV99538768; called by muse, mutect2
- EPS15 | c.2387C>T p.S796F | Missense Mutation (SNP) | VAF 60/201 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs760543648, COSV65543111; called by muse, mutect2, varscan2
- FAM83C | c.1934G>A p.R645H | Missense Mutation (SNP) | VAF 144/421 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.306); catalogued as rs538680638, COSV65582351, COSV65583477; called by muse, mutect2, varscan2
- HCFC2 | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 24/294 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57560055; called by muse, mutect2
- KCNS2 | c.43G>C p.E15Q | Missense Mutation (SNP) | VAF 18/322 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as rs1186787704, COSV99751176; called by muse, mutect2
- NEXMIF | c.1555G>C p.D519H | Missense Mutation (SNP) | VAF 18/534 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV50045540; called by muse, mutect2
- SYT10 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 94/342 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.214); catalogued as rs866874853, COSV104391111, COSV57337722; called by muse, mutect2, varscan2
- UBA2 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 13/240 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as rs1395492988; called by muse, mutect2
- ACBD3 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 101/351 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- ASIC5 | c.106A>T p.K36* | Nonsense Mutation (SNP) | VAF 131/376 reads (35%) | called by muse, mutect2, varscan2
- CRH | c.179A>G p.Q60R | Missense Mutation (SNP) | VAF 40/709 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.829); called by muse, mutect2
- KIAA1586 | c.1285G>A p.D429N | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- PDE1A | c.1183G>C p.E395Q | Missense Mutation (SNP) | VAF 13/238 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- PRR30 | c.10C>G p.Q4E | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.117); called by muse, mutect2
- SRRT | c.2026_2035dup p.S679Cfs*37 | Frame Shift Ins (INS) | VAF 78/239 reads (33%) | called by mutect2, varscan2
- TACC2 | c.5004C>G p.I1668M | Missense Mutation (SNP) | VAF 18/461 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); called by muse, mutect2
- TACR3 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 27/724 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); called by muse, mutect2
- TENM3 | c.2181T>A p.C727* | Nonsense Mutation (SNP) | VAF 115/381 reads (30%) | called by muse, mutect2, varscan2
- TTN | c.30079G>C p.D10027H (on ENST00000591111; = p.D9100H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/471 reads (8%) | PolyPhen benign (0.281); called by muse, mutect2
- TTN | c.29912G>C p.R9971T (on ENST00000591111; = p.R9044T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/280 reads (7%) | PolyPhen benign (0.172); called by muse, mutect2
- UBL4A | c.238G>C p.E80Q | Missense Mutation (SNP) | VAF 162/533 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ZNF75D | c.1222C>G p.L408V | Missense Mutation (SNP) | VAF 14/436 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.275); called by muse, mutect2
- ZNF830 | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 15/343 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADGRB2 | c.996G>C p.R332= | Silent (SNP) | VAF 45/438 reads (10%) | called by muse, mutect2, varscan2
- ARSJ | c.1500C>T p.A500= | Silent (SNP) | VAF 81/254 reads (32%) | called by muse, mutect2, varscan2
- DUSP4 | c.927C>T p.F309= | Silent (SNP) | VAF 44/466 reads (9%) | catalogued as rs1042262865, COSV53544800; called by muse, mutect2
- NBEA | c.5967G>A p.L1989= | Silent (SNP) | VAF 13/290 reads (4%) | catalogued as COSV59827741; called by muse, mutect2
- NFKBIZ | c.1767G>A p.K589= | Silent (SNP) | VAF 30/259 reads (12%) | catalogued as rs1205992164; called by muse, mutect2, varscan2
- TACC2 | c.3477C>T p.L1159= | Silent (SNP) | VAF 14/426 reads (3%) | catalogued as COSV100554018; called by muse, mutect2
- TRIM41 | c.-689C>T | 5'UTR (SNP) | VAF 96/348 reads (28%) | called by muse, mutect2, varscan2
- TULP4 | chr6:158312137 GAAGA>CC | 5'Flank (DEL) | VAF 79/273 reads (29%) | called by pindel, varscan2*
